Somatic mutation profile of tumor specimen 0DR53F from CCDI case PBCGAX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.8 years (2,866 days).
Specimen 0DR53F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6182a08e-3755-47f8-aa32-5aab88550f83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR539 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0424b0a-31da-4fcd-b2c8-9294589bedc1

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PROSER3 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 102/371 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.2); catalogued as rs1435023156; called by muse, varscan2
- KIAA1549L | c.4971C>T p.S1657= (on ENST00000321505; = p.S1954= on NM_012194.3) | Silent (SNP) | VAF 122/474 reads (26%) | called by muse, varscan2
